Somatic mutation profile of tumor specimen TARGET-20-PASTHA-09A (aliquot TARGET-20-PASTHA-09A-01D) from TARGET case TARGET-20-PASTHA, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.1 years (4,053 days).
Specimen TARGET-20-PASTHA-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1599800a-599d-4d4d-af99-e6a787ab9b7d.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASTHA-14A (Bone Marrow Normal), aliquot TARGET-20-PASTHA-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/63250a6f-3203-4bdf-a83d-9c94cc641896

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- WT1 | c.1097_1106dup p.A370Cfs*6 | Frame Shift Ins (INS) | VAF 46/161 reads (29%) | catalogued as COSV60066438, COSV60071255, COSV60072670, COSV60072961, COSV60074589; called by mutect2, varscan2
- STAG2 | c.991_992insC p.Y331Sfs*8 | Frame Shift Ins (INS) | VAF 100/125 reads (80%) | called by mutect2, pindel*, varscan2
